Somatic mutation profile of tumor specimen TCGA-AG-A026-01A (aliquot TCGA-AG-A026-01A-32W-A096-10) from TCGA case TCGA-AG-A026, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 66.8 years (24,413 days).
Specimen TCGA-AG-A026-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69a23e5d-aac4-48ac-bb2d-c1b4d13f6ca4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A026-10A (Blood Derived Normal), aliquot TCGA-AG-A026-10A-01W-A096-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b00f250-863c-4487-95f7-aeda68610452

The open-access MAF lists 238 somatic variants for this specimen: 184 protein-altering or splice-affecting, 51 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 161, Silent 51, Nonsense Mutation 8, Frame Shift Ins 5, Splice Site 4, Intron 3, Frame Shift Del 3, In Frame Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3810T>A p.C1270* | Nonsense Mutation (SNP) | VAF 91/100 reads (91%) | catalogued as rs863225347, CM000125, CX995213, COSV57342456, COSV57383570; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VWF | c.4135C>T p.R1379C | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs61750074, CM011508, COSV54633417; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC092143.1 | c.2334G>T p.E778D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.013); catalogued as COSV59249089; called by mutect2, varscan2
- ACSBG1 | c.668G>C p.W223S | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.065); catalogued as COSV51907559, COSV51910471; called by muse, mutect2, varscan2
- ACSM2A | c.1708A>G p.M570V (on ENST00000219054; = p.M491V on NM_001308169.2) | Missense Mutation (SNP) | VAF 109/372 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1254762130, COSV54589561; called by muse, mutect2, varscan2
- ACTR1A | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs368237331; called by muse, mutect2, varscan2
- ADAMDEC1 | c.786A>C p.Q262H | Missense Mutation (SNP) | VAF 66/134 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56477457; called by muse, mutect2, varscan2
- ADAMTS16 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.76); catalogued as COSV99939787, COSV99942473; called by muse, mutect2, varscan2
- ADGRG4 | c.1331G>C p.G444A | Missense Mutation (SNP) | VAF 88/262 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV99796376; called by muse, mutect2, varscan2
- ADGRL3 | c.3167A>G p.Y1056C (on ENST00000506720 / NM_001322402.2; = p.Y988C on NM_015236.6) | Missense Mutation (SNP) | VAF 230/782 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72231886; called by muse, mutect2, varscan2
- AEBP1 | c.2869G>A p.A957T | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1473933290, COSV56261112; called by muse, mutect2, varscan2
- AICDA | c.436T>C p.Y146H | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.998); catalogued as COSV99984333; called by muse, mutect2, varscan2
- ANK2 | c.5834C>T p.T1945M | Missense Mutation (SNP) | VAF 56/64 reads (88%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.006); catalogued as rs762027070, COSV52150842; called by muse, mutect2, varscan2
- ANKFY1 | c.1322C>G p.A441G | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.226); catalogued as rs765578166, COSV100493065; called by muse, mutect2, varscan2
- ARHGAP35 | c.2767C>A p.P923T | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0.062); catalogued as COSV101351501, COSV101351576; called by muse, mutect2, varscan2
- ATRNL1 | c.2740C>T p.R914* | Nonsense Mutation (SNP) | VAF 362/602 reads (60%) | catalogued as rs555650933, COSV58089715; called by muse, varscan2
- BICRA | c.2960C>A p.T987N | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.136); catalogued as COSV67606447; called by muse, mutect2, varscan2
- BMS1 | c.3486T>G p.N1162K | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); catalogued as COSV100996804; called by muse, mutect2, varscan2
- BTBD10 | c.1314C>G p.D438E | Missense Mutation (SNP) | VAF 112/346 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.679); catalogued as COSV53401520; called by muse, mutect2, varscan2
- CACNA1C | c.2693A>G p.N898S | Missense Mutation (SNP) | VAF 138/438 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100221572; called by muse, varscan2
- CARF | c.1282T>A p.L428I | Missense Mutation (SNP) | VAF 71/243 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100247830; called by muse, mutect2, varscan2
- CASP8AP2 | c.5797G>C p.D1933H | Missense Mutation (SNP) | VAF 78/132 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52749797; called by muse, mutect2, varscan2
- CBLB | c.1781G>A p.C594Y | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV99914098; called by muse, mutect2, varscan2
- CCDC71 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as rs373036352; called by muse, mutect2
- CCDC86 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 71/119 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs376975583; called by muse, mutect2, varscan2
- CCNT2 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51476553; called by muse, mutect2, varscan2
- CENPU | c.803G>T p.R268I | Missense Mutation (SNP) | VAF 129/234 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV55656783, COSV55659297; called by muse, mutect2, varscan2
- CEP350 | c.1492G>C p.E498Q | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.912); catalogued as COSV62609388; called by muse, mutect2, varscan2
- CERS3 | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 102/393 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs771534407, COSV52568754; called by muse, mutect2, varscan2
- CGA | c.224A>C p.K75T | Missense Mutation (SNP) | VAF 140/427 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63644952; called by muse, mutect2, varscan2
- CLEC2B | c.20A>G p.K7R | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.054); catalogued as COSV57310511; called by muse, mutect2, varscan2
- CMTR2 | c.591G>C p.L197F | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV57604950; called by muse, mutect2, varscan2
- COG6 | c.1659C>G p.I553M | Missense Mutation (SNP) | VAF 152/697 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as COSV62997976; called by muse, mutect2, varscan2
- COL1A2 | c.81+2T>A p.X27_splice | Splice Site (SNP) | VAF 34/115 reads (30%) | catalogued as COSV51965581, COSV99800755; called by muse, mutect2, varscan2
- COLGALT2 | c.501T>G p.D167E | Missense Mutation (SNP) | VAF 146/332 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62731228; called by muse, mutect2, varscan2
- CPNE3 | c.1611G>T p.Q537H | Missense Mutation (SNP) | VAF 78/489 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV52210500; called by muse, varscan2
- CR1 | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs1318306169, COSV100887784; called by muse, mutect2
- CSMD1 | c.10048T>C p.S3350P (on ENST00000520002; = p.S3349P on NM_033225.6) | Missense Mutation (SNP) | VAF 76/86 reads (88%) | SIFT tolerated (0.17); PolyPhen benign (0.36); catalogued as COSV100152634; called by muse, mutect2, varscan2
- CSMD3 | c.2156T>A p.F719Y (on ENST00000297405 / NM_001363185.1; = p.F615Y on NM_052900.3) | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99844239; called by muse, varscan2
- CTCF | c.71C>G p.T24S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.054); catalogued as COSV50515141; called by muse, mutect2, varscan2
- CYP2A6 | c.321C>A p.F107L | Missense Mutation (SNP) | VAF 86/424 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.055); catalogued as rs764536563, COSV99992077, COSV99992167; called by muse, mutect2, varscan2
- CYP2A6 | c.320T>A p.F107Y | Missense Mutation (SNP) | VAF 87/429 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.924); catalogued as COSV99992083; called by muse, mutect2, varscan2
- DCAF12L2 | c.917G>T p.C306F | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100758785; called by muse, mutect2, varscan2
- DCAF13 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 72/321 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as rs139907413; called by muse, mutect2, varscan2
- DENND2C | c.2243C>A p.S748Y (on ENST00000393274 / NM_001256404.2; = p.S691Y on NM_198459.4) | Missense Mutation (SNP) | VAF 206/235 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67924700; called by muse, mutect2, varscan2
- DHTKD1 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.553); catalogued as rs17849603; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLK2 | c.417-1G>A p.X139_splice | Splice Site (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99767819; called by muse, mutect2, varscan2
- DNAH11 | c.209T>C p.L70P | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100180327; called by muse, mutect2, varscan2
- DNAH17 | c.11380G>A p.E3794K | Missense Mutation (SNP) | VAF 68/104 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs758228483, COSV67757387; called by muse, mutect2, varscan2
- DOCK2 | c.2870A>T p.E957V | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.725); catalogued as COSV99914564; called by muse, mutect2
- DOCK9 | c.3572C>T p.A1191V (on ENST00000376460 / NM_001366676.2; = p.A1192V on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 191/278 reads (69%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs780668988, COSV59642440; called by muse, mutect2, varscan2
- DOP1A | c.6136G>C p.A2046P | Missense Mutation (SNP) | VAF 217/868 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV99382708; called by muse, mutect2, varscan2
- DPYSL2 | c.1249G>A p.V417I | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs771160273, COSV60784542; called by muse, mutect2, varscan2
- DRAM2 | c.157A>G p.K53E | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV54416416; called by muse, mutect2, varscan2
- DYNC1I1 | c.1351G>C p.D451H | Missense Mutation (SNP) | VAF 119/462 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100269012; called by muse, mutect2, varscan2
- ELAC2 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.779); catalogued as rs777491508, COSV62034626; called by muse, mutect2, varscan2
- EPHA7 | c.923C>A p.S308Y | Missense Mutation (SNP) | VAF 62/235 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as COSV100993288; called by muse, mutect2, varscan2
- EPN1 | c.1118C>T p.P373L (on ENST00000270460 / NM_001321263.1; = p.P348L on NM_013333.3) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs370785243; called by muse, mutect2, varscan2
- ERP27 | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 247/870 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV56764759; called by muse, mutect2, varscan2
- EVI5 | c.1109T>G p.L370R | Missense Mutation (SNP) | VAF 174/414 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100945462; called by muse, mutect2, varscan2
- EXOC6B | c.1997C>T p.T666I | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV55571817; called by muse, mutect2, varscan2
- FBXO31 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV61148543; called by muse, mutect2, varscan2
- FCRL3 | c.913A>G p.M305V | Missense Mutation (SNP) | VAF 154/340 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV63844795; called by muse, mutect2, varscan2
- FMN2 | c.3818G>T p.G1273V | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.429); catalogued as COSV60431558; called by muse, mutect2, varscan2
- GFPT2 | c.339C>T p.N113= | Splice Region (SNP) | VAF 110/131 reads (84%) | catalogued as rs1284403797, COSV53812294; called by muse, mutect2, varscan2
- GKAP1 | c.365C>A p.T122K | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV64489770; called by muse, mutect2, varscan2
- GOLGA7B | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1007342675, COSV54001982; called by muse, mutect2, varscan2
- GPR18 | c.24T>A p.D8E | Missense Mutation (SNP) | VAF 297/462 reads (64%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV61621501; called by muse, mutect2, varscan2
- GRM3 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 233/420 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.177); catalogued as rs267601603, COSV64469163; called by muse, mutect2, varscan2
- GXYLT1 | c.276T>A p.D92E | Missense Mutation (SNP) | VAF 148/513 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV55142416; called by muse, mutect2, varscan2
- HACE1 | c.751T>C p.Y251H | Missense Mutation (SNP) | VAF 291/496 reads (59%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs774982768, COSV99494171; called by mutect2, varscan2
- HDC | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 54/126 reads (43%) | catalogued as rs750405599, COSV51068254; called by muse, mutect2, varscan2
- HS3ST2 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54468440; called by muse, mutect2
- HUNK | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 71/241 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs576162040, COSV54225776; called by muse, mutect2, varscan2
- IGSF21 | c.890G>A p.G297D | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99245906; called by muse, mutect2, varscan2
- INSYN2A | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs150869481; called by muse, mutect2
- IQCE | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1467701635, COSV58076641; called by muse, mutect2, varscan2
- IRAG2 | c.3050A>T p.N1017I (on ENST00000636465; = p.N62I on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 104/356 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV63140795; called by muse, mutect2, varscan2
- IVNS1ABP | c.1445G>C p.C482S | Missense Mutation (SNP) | VAF 169/852 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV62252057; called by muse, mutect2, varscan2
- KANSL3 | c.2396C>T p.T799I (on ENST00000666923 / NM_001349262.2; = p.T773I on NM_001115016.3) | Missense Mutation (SNP) | VAF 127/207 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.288); catalogued as COSV62617677; called by muse, mutect2, varscan2
- KCNB2 | c.1203C>A p.C401* | Nonsense Mutation (SNP) | VAF 91/168 reads (54%) | catalogued as COSV101578950, COSV73052226; called by muse, mutect2, varscan2
- KIF11 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 88/331 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99586084, COSV99586239; called by muse, mutect2, varscan2
- KIF20B | c.3581T>C p.I1194T (on ENST00000371728 / NM_001284259.2; = p.I1154T on NM_016195.4) | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV99590590; called by muse, mutect2, varscan2
- KLF6 | c.392G>A p.G131D | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.343); catalogued as COSV51496175; called by muse, mutect2, varscan2
- KRT73 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as rs993341388, COSV59838270; called by muse, mutect2, varscan2
- L3MBTL4 | c.172T>G p.L58V | Missense Mutation (SNP) | VAF 84/193 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53139651; called by muse, mutect2, varscan2
- LCE1F | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 75/137 reads (55%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.011); catalogued as rs781644957, COSV57670187; called by muse, mutect2, varscan2
- LIG3 | c.2759A>G p.K920R | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99253014; called by muse, mutect2
- LILRB5 | c.1104G>T p.K368N | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as COSV100300706; called by muse, mutect2, varscan2
- LIMK1 | c.1809G>A p.W603* | Nonsense Mutation (SNP) | VAF 43/77 reads (56%) | catalogued as COSV100283400; called by muse, mutect2, varscan2
- LYPLAL1 | c.167T>C p.I56T | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); catalogued as COSV65107137; called by muse, mutect2, varscan2
- MAGEB18 | c.143G>T p.R48I | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV57465009; called by muse, mutect2, varscan2
- MPP4 | c.726G>T p.Q242H | Missense Mutation (SNP) | VAF 80/248 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV59634292; called by muse, mutect2, varscan2
- MUC16 | c.35911A>C p.T11971P | Missense Mutation (SNP) | VAF 233/1108 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV101201038; called by muse, mutect2, varscan2
- MUC16 | c.9097A>T p.S3033C | Missense Mutation (SNP) | VAF 143/295 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV101201039; called by muse, mutect2, varscan2
- MYO10 | c.2437G>C p.A813P | Missense Mutation (SNP) | VAF 89/369 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.132); catalogued as COSV99946056; called by muse, mutect2, varscan2
- NAV2 | c.4940G>A p.R1647H | Missense Mutation (SNP) | VAF 174/638 reads (27%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs771139211, COSV100217527; called by muse, mutect2, varscan2
- NCEH1 | c.497A>G p.Y166C (on ENST00000538775; = p.Y126C on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.525); catalogued as COSV56438136; called by muse, mutect2, varscan2
- NEBL | c.2905G>A p.D969N | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101009311; called by muse, mutect2, varscan2
- NEDD4 | c.3579+2T>C p.X1193_splice (on ENST00000508342 / NM_001284338.1; = p.X774_splice on NM_006154.4) | Splice Site (SNP) | VAF 112/256 reads (44%) | catalogued as COSV59066431; called by muse, mutect2, varscan2
- NOS1 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 67/189 reads (35%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.736); catalogued as COSV100501256; called by muse, mutect2, varscan2
- NPTN | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 174/585 reads (30%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.505); catalogued as COSV54739834; called by muse, mutect2, varscan2
- NPTX2 | c.1196C>G p.P399R | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.922); catalogued as COSV55719534, COSV99675050; called by muse, mutect2, varscan2
- OBSCN | c.13442C>G p.T4481S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV52825738; called by muse, mutect2, varscan2
- OR2L13 | c.124T>C p.S42P | Missense Mutation (SNP) | VAF 275/1182 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.226); catalogued as COSV63560511; called by muse, mutect2, varscan2
- OR6M1 | c.724A>G p.I242V | Missense Mutation (SNP) | VAF 94/306 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV100484156; called by muse, mutect2, varscan2
- OR8K1 | c.328T>G p.F110V | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as COSV54401231, COSV54401510; called by muse, mutect2, varscan2
- OTUD7B | c.910C>T p.H304Y | Missense Mutation (SNP) | VAF 138/320 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100967731; called by muse, mutect2, varscan2
- P2RY10 | c.649T>A p.C217S | Missense Mutation (SNP) | VAF 116/558 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.836); catalogued as COSV50685884; called by muse, mutect2, varscan2
- PCDH11X | c.3615C>G p.I1205M | Missense Mutation (SNP) | VAF 246/725 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV53455584, COSV53502052; called by muse, mutect2, varscan2
- PCDH9 | c.3685A>G p.T1229A (on ENST00000377865 / NM_203487.3; = p.T1195A on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 175/662 reads (26%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1306130039, COSV100122776; called by muse, mutect2, varscan2
- PCDHA12 | c.1313C>T p.T438M | Missense Mutation (SNP) | VAF 24/25 reads (96%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.947); catalogued as rs1554168921, COSV100248406; called by muse, mutect2, varscan2
- PCDHGA2 | c.1558T>A p.F520I | Missense Mutation (SNP) | VAF 97/187 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV54026866; called by muse, mutect2, varscan2
- PCDHGC4 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 113/136 reads (83%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as COSV52767311; called by muse, mutect2, varscan2
- PDE10A | c.279A>T p.E93D | Missense Mutation (SNP) | VAF 345/588 reads (59%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.956); catalogued as COSV100605559, COSV63099939; called by muse, mutect2, varscan2
- PGBD5 | c.382C>T p.R128C (on ENST00000525115; = p.R197C on NM_001258311.2) | Missense Mutation (SNP) | VAF 60/251 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs148878203; called by muse, mutect2, varscan2
- PKN2 | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 79/179 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV100281708; called by muse, mutect2, varscan2
- PLB1 | c.2775C>A p.S925R | Missense Mutation (SNP) | VAF 65/267 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.984); catalogued as COSV100578788, COSV59835048; called by muse, mutect2, varscan2
- PLCG2 | c.1385G>T p.G462V | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV100842558; called by muse, mutect2
- PMPCB | c.339G>C p.K113N | Missense Mutation (SNP) | VAF 89/313 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.047); catalogued as COSV50787981; called by muse, mutect2, varscan2
- POTEE | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.141); catalogued as rs530766889, COSV58227595, COSV58239743; called by muse, mutect2, varscan2
- PRSS54 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 73/123 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs367701903; called by muse, mutect2, varscan2
- RANBP2 | c.7122G>T p.R2374S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51708341; called by muse, mutect2, varscan2
- RASSF2 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 133/290 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs755440456, COSV65082183, COSV65083191; called by muse, mutect2, varscan2
- RB1CC1 | c.3973A>G p.I1325V | Missense Mutation (SNP) | VAF 56/327 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as rs774629394, COSV99212652; called by muse, mutect2, varscan2
- RGS9 | c.1444G>A p.V482M | Missense Mutation (SNP) | VAF 286/496 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs1468415333, COSV52226788; called by muse, mutect2, varscan2
- RHBDD1 | c.806G>A p.S269N | Missense Mutation (SNP) | VAF 132/418 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs910346351, COSV58131373; called by muse, mutect2, varscan2
- RP1 | c.3388C>G p.L1130V | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99608525; called by muse, mutect2, varscan2
- RSPO2 | c.313T>C p.F105L | Missense Mutation (SNP) | VAF 90/447 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99410188; called by muse, mutect2, varscan2
- RYR1 | c.6724A>G p.I2242V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100616686; called by muse, mutect2, varscan2
- SDHA | c.743G>C p.R248T | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as COSV53771350; called by muse, mutect2, varscan2
- SEMG2 | c.1429C>T p.R477* | Nonsense Mutation (SNP) | VAF 52/360 reads (14%) | catalogued as rs546357756, COSV65647159; called by muse, mutect2, varscan2
- SGSH | c.919C>G p.Q307E | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV58340567; called by muse, mutect2, varscan2
- SH3GL3 | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); catalogued as COSV61053874; called by muse, mutect2, varscan2
- SKAP2 | c.423G>T p.W141C | Missense Mutation (SNP) | VAF 95/563 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61727681; called by muse, mutect2, varscan2
- SLC6A14 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 430/802 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV100903214; called by muse, mutect2, varscan2
- SLC7A3 | c.559G>C p.A187P | Missense Mutation (SNP) | VAF 128/140 reads (91%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV53229193; called by muse, mutect2, varscan2
- SLITRK5 | c.2739A>T p.E913D | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as COSV100281093; called by muse, mutect2, varscan2
- SOCS5 | c.1571G>C p.R524T | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100125426, COSV60606085; called by muse, mutect2, varscan2
- SOGA1 | c.3125C>T p.A1042V | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV99414904; called by muse, mutect2, varscan2
- SRCAP | c.7138C>T p.R2380W | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV52680434; called by muse, mutect2, varscan2
- SYT7 | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 71/203 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs747884194, COSV55653943; called by muse, mutect2, varscan2
- TAS2R8 | c.367A>C p.K123Q | Missense Mutation (SNP) | VAF 61/203 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99553924; called by muse, mutect2, varscan2
- TBC1D4 | c.2965C>G p.L989V | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100884757; called by muse, mutect2, varscan2
- TJAP1 | c.267C>G p.D89E | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.99); catalogued as COSV52503695; called by muse, mutect2, varscan2
- TLR9 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as rs749742285, COSV62345958; called by muse, mutect2, varscan2
- TMEM104 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV59112117; called by muse, mutect2, varscan2
- TMEM43 | c.692C>G p.P231R | Missense Mutation (SNP) | VAF 43/231 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100044527, COSV60146068; called by muse, mutect2, varscan2
- TP53 | c.97-2_97-1dup p.L35Pfs*10 | Frame Shift Ins (INS) | VAF 192/292 reads (66%) | catalogued as COSV53359775, COSV99475020; called by mutect2, pindel, varscan2
- TPRX1 | c.395C>A p.P132Q | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV100445864; called by muse, mutect2, varscan2
- TTN | c.59401G>C p.A19801P (on ENST00000591111; = p.A12377P on NM_003319.4) | Missense Mutation (SNP) | VAF 53/165 reads (32%) | PolyPhen possibly damaging (0.883); catalogued as COSV60331058; called by muse, mutect2, varscan2
- UBAP2L | c.1610C>T p.T537I | Missense Mutation (SNP) | VAF 70/308 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV99672063; called by muse, mutect2, varscan2
- UNC5C | c.2014C>A p.H672N | Missense Mutation (SNP) | VAF 76/285 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV101498002; called by muse, mutect2, varscan2
- USP34 | c.5907G>T p.Q1969H | Missense Mutation (SNP) | VAF 103/364 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101277162; called by muse, mutect2, varscan2
- VPS13B | c.4223T>G p.L1408R | Missense Mutation (SNP) | VAF 174/961 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100663110; called by muse, mutect2, varscan2
- WNT6 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs766635655, COSV99293293; called by muse, mutect2
- YY1AP1 | c.1910C>A p.A637D (on ENST00000295566 / NM_139118.2; = p.A580D on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/277 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as COSV55122155, COSV55124649; called by muse, mutect2, varscan2
- ZDHHC19 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV56349971; called by muse, mutect2, varscan2
- ZFR | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 143/607 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99416390; called by muse, mutect2, varscan2
- ZIM3 | c.1201T>C p.F401L | Missense Mutation (SNP) | VAF 153/453 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV54146450; called by muse, mutect2, varscan2
- ZNF23 | c.836C>G p.P279R | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61841685; called by muse, mutect2, varscan2
- ZNF266 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 91/462 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100749433; called by muse, mutect2, varscan2
- ZNF280C | c.873C>G p.I291M | Missense Mutation (SNP) | VAF 56/400 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100921263; called by muse, mutect2, varscan2
- ZNF287 | c.851T>C p.F284S | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.283); catalogued as COSV101209415; called by muse, mutect2, varscan2
- ZNF330 | c.865A>G p.K289E | Missense Mutation (SNP) | VAF 182/297 reads (61%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV53708421; called by muse, mutect2, varscan2
- ZNF521 | c.2720G>A p.R907Q | Missense Mutation (SNP) | VAF 190/430 reads (44%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.97); catalogued as COSV64125945; called by muse, varscan2
- ZNF528 | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as COSV100846712; called by muse, mutect2, varscan2
- ZNF568 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as rs765837806, COSV61741888; called by muse, mutect2, varscan2
- ZNF582 | c.441A>C p.E147D | Missense Mutation (SNP) | VAF 127/499 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV100018886; called by muse, mutect2, varscan2
- ZNF607 | c.432T>G p.C144W | Missense Mutation (SNP) | VAF 110/432 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100777942; called by muse, mutect2, varscan2
- ZNF83 | c.47A>C p.Q16P | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99991517; called by muse, mutect2, varscan2
- ZP4 | c.704T>A p.F235Y | Missense Mutation (SNP) | VAF 73/402 reads (18%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.914); catalogued as COSV63913402; called by muse, mutect2, varscan2
- ACO1 | c.1765dup p.I589Nfs*5 | Frame Shift Ins (INS) | VAF 76/216 reads (35%) | called by mutect2, pindel, varscan2
- ARID2 | c.109dup p.I37Nfs*29 | Frame Shift Ins (INS) | VAF 19/34 reads (56%) | called by mutect2, varscan2
- FGD2 | c.1217dup p.M406Ifs*13 | Frame Shift Ins (INS) | VAF 41/229 reads (18%) | called by mutect2, varscan2
- FGD2 | c.1218delinsTT p.M406Ifs*13 | Frame Shift Ins (INS) | VAF 49/304 reads (16%) | called by mutect2*, pindel, varscan2*
- HECA | c.334_336del p.D112del | In Frame Del (DEL) | VAF 39/77 reads (51%) | called by pindel, varscan2
- LVRN | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- NID1 | c.526-1_527delinsTA p.X176_splice | Splice Site (DEL) | VAF 28/120 reads (23%) | called by pindel, varscan2*
- PHF14 | c.2574del p.L858Ffs*10 | Frame Shift Del (DEL) | VAF 96/572 reads (17%) | called by mutect2, varscan2
- PHF14 | c.2575C>T p.Q859* | Nonsense Mutation (SNP) | VAF 98/571 reads (17%) | called by mutect2, varscan2
- PTCHD4 | c.2171_2195del p.F724Cfs*7 | Frame Shift Del (DEL) | VAF 106/224 reads (47%) | called by mutect2, pindel, varscan2
- PUS7L | c.38_54del p.S13* | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- UTP23 | c.26_40del p.A9_L13del | In Frame Del (DEL) | VAF 12/88 reads (14%) | called by mutect2, pindel
- ADA2 | c.798G>A p.V266= (on ENST00000262607; = p.V25= on NM_177405.3) | Silent (SNP) | VAF 99/234 reads (42%) | catalogued as COSV52833759; called by muse, mutect2, varscan2
- ALG8 | c.1227G>C p.L409= | Silent (SNP) | VAF 193/617 reads (31%) | catalogued as COSV55202963; called by muse, mutect2, varscan2
- CAD | c.3813G>A p.L1271= | Silent (SNP) | VAF 36/125 reads (29%) | catalogued as COSV53031563; called by muse, mutect2, varscan2
- CARMIL3 | c.3048C>T p.F1016= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV100549010, COSV57728263; called by muse, mutect2, varscan2
- CAT | c.1344G>C p.V448= | Silent (SNP) | VAF 76/246 reads (31%) | catalogued as COSV53813253; called by muse, mutect2, varscan2
- CCDC113 | c.972C>T p.Y324= | Silent (SNP) | VAF 173/313 reads (55%) | catalogued as rs571059899, COSV54687761; called by muse, mutect2, varscan2
- CCDC178 | c.1602A>G p.E534= | Silent (SNP) | VAF 63/172 reads (37%) | catalogued as COSV55796221; called by muse, mutect2, varscan2
- CDH18 | c.1116C>A p.I372= | Silent (SNP) | VAF 92/405 reads (23%) | catalogued as COSV56958872, COSV56967697; called by muse, mutect2, varscan2
- CLSPN | c.675T>C p.S225= | Silent (SNP) | VAF 102/256 reads (40%) | catalogued as rs777818827, COSV52056867; called by muse, mutect2, varscan2
- COG8 | c.1629G>A p.V543= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99846573; called by muse, mutect2, varscan2
- CSH2 | c.87C>A p.T29= | Silent (SNP) | VAF 30/197 reads (15%) | catalogued as rs753371030, COSV61081035, COSV61081240; called by muse, mutect2, varscan2
- DIAPH3 | c.786A>G p.R262= | Silent (SNP) | VAF 79/333 reads (24%) | catalogued as COSV57380610; called by muse, mutect2, varscan2
- DMD | c.5221T>C p.L1741= | Silent (SNP) | VAF 224/527 reads (43%) | catalogued as rs1228749524, COSV63747107, COSV63789783; called by muse, mutect2, varscan2
- DNASE2 | c.693C>T p.F231= | Silent (SNP) | VAF 44/186 reads (24%) | catalogued as COSV52254549; called by muse, mutect2, varscan2
- DOCK1 | c.1515C>T p.N505= | Silent (SNP) | VAF 80/224 reads (36%) | catalogued as rs774326772, COSV54759241; called by muse, mutect2, varscan2
- DRD5 | c.303C>T p.A101= | Silent (SNP) | VAF 36/58 reads (62%) | catalogued as COSV58580305; called by muse, mutect2, varscan2
- FAT3 | c.1257C>T p.Y419= | Silent (SNP) | VAF 36/134 reads (27%) | catalogued as COSV53170798, COSV99965747; called by muse, mutect2, varscan2
- HECTD4 | c.11136C>G p.G3712= | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as COSV66399548; called by muse, mutect2, varscan2
- HS3ST3A1 | c.129C>T p.A43= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV52379165; called by muse, mutect2, varscan2
- KCNB2 | c.2034C>T p.L678= | Silent (SNP) | VAF 26/189 reads (14%) | catalogued as rs374713448; called by muse, mutect2, varscan2
- LRRC43 | c.456G>A p.E152= | Silent (SNP) | VAF 74/236 reads (31%) | catalogued as COSV60293293; called by muse, mutect2, varscan2
- LY6K | c.246G>A p.A82= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as rs782387825, COSV52832165; called by muse, mutect2, varscan2
- MARS2 | c.1683A>G p.P561= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs1397076906, COSV56572384; called by muse, mutect2, varscan2
- MAST2 | c.4248C>T p.A1416= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as rs762803738, COSV63621366; called by muse, mutect2, varscan2
- ME3 | c.1350C>T p.C450= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV62775009; called by muse, mutect2, varscan2
- MESP2 | c.1017C>T p.P339= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs370227491; called by muse, mutect2, varscan2
- MSX2 | c.39C>T p.P13= | Silent (SNP) | VAF 15/16 reads (94%) | catalogued as rs766427771, COSV53328244; called by muse, mutect2, varscan2
- NCKAP1 | c.564T>A p.P188= | Silent (SNP) | VAF 340/1086 reads (31%) | catalogued as rs749683028, COSV62943449; called by muse, mutect2, varscan2
- NEUROD1 | c.72C>T p.D24= | Silent (SNP) | VAF 137/211 reads (65%) | catalogued as rs1284838712, COSV54548790; called by muse, mutect2, varscan2
- NTSR2 | c.1044C>T p.Y348= | Silent (SNP) | VAF 41/150 reads (27%) | catalogued as rs143067546; called by muse, mutect2, varscan2
- OR6K6 | c.1017T>G p.G339= (on ENST00000368144; = p.G315= on NM_001005184.1) | Silent (SNP) | VAF 44/235 reads (19%) | catalogued as COSV63744861; called by muse, mutect2, varscan2
- ORC5 | c.1059G>C p.G353= | Silent (SNP) | VAF 181/587 reads (31%) | catalogued as COSV52402589; called by muse, mutect2, varscan2
- PAGE5 | c.9G>A p.A3= | Silent (SNP) | VAF 66/160 reads (41%) | catalogued as rs748799326, COSV56944532; called by muse, mutect2, varscan2
- PKLR | c.1014G>A p.G338= | Silent (SNP) | VAF 95/419 reads (23%) | catalogued as COSV100712995; called by mutect2, varscan2
- PLA2G2F | c.633C>A p.P211= | Silent (SNP) | VAF 22/26 reads (85%) | catalogued as COSV64280104, COSV64280357; called by muse, mutect2, varscan2
- PLEKHG4B | c.3540C>T p.H1180= (on ENST00000283426; = p.H1536= on NM_052909.5) | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as rs115843378, COSV52045381; called by muse, mutect2, varscan2
- PPP2R2C | c.1029A>G p.E343= | Silent (SNP) | VAF 185/201 reads (92%) | catalogued as COSV59447595; called by muse, mutect2, varscan2
- PROSER1 | c.1842T>C p.P614= | Silent (SNP) | VAF 144/561 reads (26%) | catalogued as COSV61489554; called by muse, mutect2, varscan2
- RALA | c.528A>T p.R176= | Silent (SNP) | VAF 102/264 reads (39%) | catalogued as COSV50050348; called by muse, mutect2, varscan2
- SCN3A | c.2592C>T p.S864= | Silent (SNP) | VAF 24/226 reads (11%) | catalogued as COSV51802250, COSV51823632; called by muse, mutect2, varscan2
- SHQ1 | c.1143C>G p.L381= | Silent (SNP) | VAF 43/205 reads (21%) | catalogued as COSV57768256; called by muse, mutect2, varscan2
- SLC26A11 | c.159C>A p.V53= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV58340571; called by muse, mutect2, varscan2
- SLC4A4 | c.2481C>G p.A827= (on ENST00000264485 / NM_001098484.3; = p.A783= on NM_003759.4) | Silent (SNP) | VAF 39/1214 reads (3%) | catalogued as COSV99141515; called by muse, mutect2
- SPATA31A1 | c.1479T>G p.P493= | Silent (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- SPATC1 | c.1395C>T p.R465= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs782332850, COSV66299979; called by muse, mutect2, varscan2
- TF | c.2001A>G p.E667= | Silent (SNP) | VAF 54/169 reads (32%) | catalogued as rs1296158428, COSV53924034; called by muse, mutect2, varscan2
- THAP11 | c.543T>C p.T181= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs1165176795, COSV99534566; called by muse, mutect2
- USP9X | c.1470G>A p.L490= | Silent (SNP) | VAF 199/344 reads (58%) | catalogued as COSV61074886; called by muse, mutect2, varscan2
- VAX2 | c.780C>T p.A260= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as rs1553414645, COSV52267366; called by muse, mutect2, varscan2
- WDR64 | c.1596G>C p.G532= | Silent (SNP) | VAF 98/614 reads (16%) | catalogued as COSV100843660, COSV63800308; called by muse, mutect2, varscan2
- ZNF570 | c.678C>G p.V226= | Silent (SNP) | VAF 49/175 reads (28%) | catalogued as COSV57580755; called by muse, mutect2, varscan2
- LRRFIP1 | c.154-5264_154-5255del | Intron (DEL) | VAF 135/755 reads (18%) | called by mutect2, pindel, varscan2
- MRC1 | c.917-133dup | Intron (INS) | VAF 158/582 reads (27%) | called by mutect2, varscan2
- TTN | c.10360+1253T>G | Intron (SNP) | VAF 34/88 reads (39%) | catalogued as COSV59861821, COSV59870423; called by muse, mutect2, varscan2
